Gene-level copy-number profile of tumor specimen C3L-05870-57 from CPTAC case C3L-05870, project CPTAC-3 (Hematopoietic and reticuloendothelial systems — Myeloid Leukemias). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 61.2 years (22,356 days).
Specimen C3L-05870-57: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 54d9057f-d658-4ed0-a2f4-ecdcc346a5b0.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-05870-50 (buccal cell normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,222 have no estimate.
https://portal.gdc.cancer.gov/files/29989b53-b9dc-43c3-82f7-763966d81b02

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 4,246; copy number 2: 47,714; copy number 3: 5,261; copy number 4: 1,062; copy number 5: 118.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 118 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:537,527–1,908,656, 76 genes, copy number 5 (broad region; genes not listed).
- chr11:3,087,107–3,581,211, 24 genes, copy number 5: OSBPL5, AC108448.1, MRGPRG, MRGPRG-AS1, MRGPRE, AC109309.1, NDUFA5P8, AC109309.2, NDUFA5P1, AC123788.2, AC123788.1, ZNF195, TSSC2, OR7E12P, FAM86GP, AC127526.3, AC127526.1, AC127526.5, AC127526.2, AC127526.4, SNRPCP5, RPS3AP39, RPS24P14, AP006294.2.
- chr11:3,671,083–4,093,210, 15 genes, copy number 5 (within-gene range 3–5): NUP98, RNU6-1143P, RNU7-50P, PGAP2, RHOG, STIM1-AS1, STIM1, AC090587.1, MIR4687, PPIAP40, AC087441.1, AC087441.3, HNRNPA1P76, AC087441.2, RPS29P20.
- chr11:4,637,477–4,661,763, 3 genes, copy number 5: OR51D1, OR51E1, OR51A9P.

Autosomal genes at a single copy (total copy number 1): 4,246. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
